Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A3JQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A3JQ-01A (Primary Tumor).

[page 1 of 3]
100-0-3

carcinoma, serous, NOS
Site: Endometrium C54.1

8441/3

bw
12/11/11

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Abdomen, panniculectomy: Skin and subcutaneous tissue, 2218.0 grams, identified grossly.
- B. Uterus, right and left ovaries and fallopian tubes, hysterectomy, and bilateral salpingo-oophorectomy: FIGO grade III (of III) endometrial adenocarcinoma, serous adenocarcinoma is identified forming a polypoid mass 2.9 x 2.0 x 2.0 cm, located in the anterior uterine wall and also extending to involve the posterior endometrioid surface over a 5.0 x 3.5 x 2.0 cm area (total). The tumor invades 0.1 cm into the myometrium (total wall thickness 3.2 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are not involved.
- C. Lymph nodes, left pelvic, excision: Multiple (8) lymph nodes are negative for tumor.
- D. Lymph nodes, right pelvic, excision: One of twenty lymph nodes (1 of 20) lymph nodes is positive for metastatic adenocarcinoma.
- E. Omentum, omentectomy: Fibroadipose tissue. Negative for tumor. One (1) regional lymph node is negative for tumor.
- F. Lymph nodes, right para-aortic excision: Multiple (9) lymph nodes are negative for tumor.
- G. Gonadal vessel, right, excision: Negative for tumor.
- H. Lymph nodes, left para-aortic, excision: Multiple (11) lymph nodes are negative for tumor.
- I. Gonadal vessel, left, excision: Focal involvement by metastatic adenocarcinoma is identified.
- J-T: Staging biopsies [cul-de-sac, bladder peritoneum, right colic gutter, left colic gutter, right pelvic sidewall, left pelvic sidewall, small bowel serosa, small bowel mesentery, large bowel serosa, large bowel mesentery, and right diaphragm] biopsies: Negative for tumor, all specimens.

with available surgical material [AJCC pT2b N1] (7th edition, 2010).

PRELIMINARY FROZEN SECTION CONSULTATION:

- A. Abdomen, panniculectomy: Skin and subcutaneous tissue, 2218.0 grams, identified grossly.
- B. Uterus, right and left ovaries and fallopian tubes, hysterectomy, and bilateral salpingo-oophorectomy: FIGO grade III (of III) endometrial adenocarcinoma, serous adenocarcinoma is identified forming a polypoid mass 2.9 x 2.0 x 2.0 cm, located in the anterior uterine wall and also extending to involve the posterior endometrioid surface over a 5.0 x 3.5 x 2.0 cm area (total). The tumor invades 0.1 cm into the myometrium (total wall thickness 3.2 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are not involved.

with available surgical material [AJCC pT1a] (7th edition, 2010).

[page 2 of 3]
- C. Lymph nodes, left pelvic, excision: Multiple (8) lymph nodes are negative for tumor.
- D. Lymph nodes, right pelvic, excision: Multiple (20) lymph nodes are negative for tumor.
- E. Omentum, omentectomy: Fibroadipose tissue. Negative for tumor. One (1) regional lymph node is negative for tumor.
- F. Lymph nodes, right para-aortic excision: Multiple (9) lymph nodes are negative for tumor.
- G. Gonadal vessel, right, excision: Negative for tumor.
- H. Lymph nodes, left para-aortic, excision: Multiple (11) lymph nodes are negative for tumor.
- I. Gonadal vessel, left, excision: Negative for tumor.
- J-T: Staging biopsies [cul-de-sac, bladder peritoneum, right colic gutter, left colic gutter, right pelvic sidewall, left pelvic sidewall, small bowel serosa, small bowel mesentery, large bowel serosa, large bowel mesentery, and right diaphragm] biopsies: Negative for tumor, all specimens.

GROSS DESCRIPTION:

- A. Received fresh labeled "pannus" is a 2218.0 gram portion of skin and subcutaneous tissue, without umbilicus. No lesions identified. Gross only.
- B. Received fresh labeled "uterus with bilateral fallopian tubes and ovaries" is a 192.0 gram uterus with attached bilateral tubes and ovaries. The uterine serosa is smooth. There is a 5.0 x 3.5 x 0.2 cm involving the entire endometrium with a 2.9 x 2.0 x 2.0 cm polypoid mass in the anterior of the endometrial cavity without invasion. The myometrial thickness is 3.2 cm. There are no uterine leiomyomata. There is a 2.0 x 1.0 x 0.6 cm right ovary with a smooth outer surface and a solid cut surface with a 6.0 x 0.3 cm right previously ligated fallopian tube which is unremarkable. There is a 2.0 x 1.2 x 0.6 cm left ovary with a smooth outer surface and a solid cut surface with a 4.0 x 0.3 cm left fallopian tube which has multiple paratubal cysts. Representative sections submitted.
- C. Received fresh labeled "left pelvic lymph nodes" is an 8.4 x 8.3 x 2.5 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.
- D. Received fresh labeled "right pelvic lymph nodes" is an 11.5 x 7.0 x 2.0 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.
- E. Received fresh labeled "omentum" is a 33.0 x 15.0 x 4.0 cm portion of omentum. No masses are identified grossly. Lymph nodes are identified. Representative sections are submitted.
- F. Received fresh labeled "right para-aortic lymph nodes" is a 6.5 x 2.5 x 1.3 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.
- G. Received fresh labeled "right gonadal vessels" is a 3.7 cm in length by 0.6 cm in diameter portion of unremarkable tubular tissue. Representative sections are submitted.
- H. Received fresh labeled "left para aortic lymph nodes" is a 5.2 x 4.2 x 1.5 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.
- I. Received fresh labeled "left gonadal vessels" is a 4.3 cm in length by 0.3 cm in diameter portion of unremarkable blood vessel. A representative section is submitted.
- J. Received fresh labeled "cul-de-sac" is a 0.3 x 0.3 x 0.1 cm

[page 3 of 3]
- aggregate of yellow soft tissue which is entirely submitted.
- K. Received fresh labeled "bladder peritoneum" is a 0.8 x 0.4 x 0.1 cm aggregate of yellow soft tissue which is entirely submitted.
- L. Received fresh labeled "right colic gutter" is a 1.3 x 1.3 x 0.3 cm aggregate of yellow soft tissue which is entirely submitted.
- M. Received fresh labeled "left colic gutter" is a 1.5 x 1.3 x 0.2 cm aggregate of yellow soft tissue which is entirely submitted.
- N. Received fresh labeled "right pelvic sidewall" is a 0.7 x 0.5 x 0.3 cm aggregate of yellow soft tissue which is entirely submitted.
- O. Received fresh labeled "left pelvic sidewall" is a 0.6 x 0.3 x 0.2 cm aggregate of yellow soft tissue which is entirely submitted.
- P. Received fresh labeled "small bowel serosa" is a 0.3 x 0.3 x 0.3 cm aggregate of yellow soft tissue which is entirely submitted.
- Q. Received fresh labeled "small bowel mesentery" is a 0.5 x 0.3 x 0.2 cm aggregate of yellow soft tissue which is entirely submitted.
- R. Received fresh labeled "large bowel serosa" is a 0.4 x 0.3 x 0.2 cm aggregate of yellow soft tissue which is entirely submitted.
- S. Received fresh labeled "large bowel mesentery" is a 0.6 x 0.5 x 0.3 cm aggregate of yellow soft tissue which is entirely submitted.
- T. Received fresh labeled "right diaphragm" is a 0.3 x 0.2 x 0.2 cm aggregate of yellow soft tissue which is entirely submitted.

Source: NCI Genomic Data Commons file d4c3e118-4297-4001-b62e-4cc576516648 (TCGA-D1-A3JQ.2001A1EC-1385-4EB3-BC9E-7E48143FD663.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).